Somatic mutation profile of tumor specimen C3N-02082-01 (aliquot CPT0109920007) from CPTAC case C3N-02082, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.9 years (24,439 days).
Specimen C3N-02082-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd466c8c-a5e0-4075-84dc-9f3920189074.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02082-71 (Blood Derived Normal), aliquot CPT0146260002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8240ebd4-3154-45d1-afc5-35c2de14b489

The open-access MAF lists 67 somatic variants for this specimen: 43 protein-altering or splice-affecting, 14 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 14, Intron 6, RNA 2, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 2, In Frame Del 1, Splice Region 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRSS1 | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 70/412 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs193922655; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- VHL | c.227_229del p.F76del | In Frame Del (DEL) | VAF 86/466 reads (18%) | hotspot (GDC flag); catalogued as rs5030648; called by pindel, varscan2
- AASS | c.1429A>G p.M477V | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1318321356; called by muse, mutect2, varscan2
- ADCY2 | c.2677A>T p.I893F | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57858646; called by muse, mutect2
- ATRAID | c.190C>T p.L64F (on ENST00000611786; = p.L9F on NM_001170795.3) | Missense Mutation (SNP) | VAF 123/662 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs185160026; called by muse, mutect2, varscan2
- BCAS3 | c.2371A>T p.R791W (on ENST00000390652 / NM_001353144.2; = p.R776W on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV66781326; called by muse, varscan2
- CACNA2D4 | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.212); catalogued as rs1452597468; called by muse, mutect2, varscan2
- CELSR3 | c.3961G>A p.V1321I | Missense Mutation (SNP) | VAF 93/421 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs755921834, COSV51131724, COSV51156474; called by muse, mutect2, varscan2
- FLG | c.7445T>A p.V2482E | Missense Mutation (SNP) | VAF 87/573 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64244987; called by muse, mutect2, varscan2
- IPO7 | c.3020-2A>G p.X1007_splice | Splice Site (SNP) | VAF 21/100 reads (21%) | catalogued as rs774216535, COSV65687154; called by muse, mutect2, varscan2
- RAB3GAP1 | c.824C>G p.P275R | Missense Mutation (SNP) | VAF 67/434 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51487600; called by muse, mutect2, varscan2
- TNFSF8 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs746569681; called by muse, mutect2, varscan2
- ARHGAP35 | c.4408C>G p.Q1470E | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP7A | c.1685G>T p.G562V | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- DAGLB | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- DLX3 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 66/411 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- DNAH7 | c.7226T>C p.L2409P | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DSC2 | c.2586A>T p.R862S | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- FAM76A | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- FBN2 | c.538T>A p.C180S | Missense Mutation (SNP) | VAF 61/486 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- FBXL19 | c.382-1G>A p.X128_splice | Splice Site (SNP) | VAF 48/272 reads (18%) | called by muse, mutect2, varscan2
- KCNU1 | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- KIAA1549 | c.3911G>C p.G1304A | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLC1 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 75/422 reads (18%) | called by muse, mutect2, varscan2
- LRP2 | c.9762G>T p.M3254I | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MXRA5 | c.1408del p.Q470Rfs*8 | Frame Shift Del (DEL) | VAF 46/235 reads (20%) | called by mutect2, pindel, varscan2
- OR10D3 | c.58A>T p.T20S | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- OR5K3 | c.214T>A p.C72S | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PARD6B | c.213del p.I72* | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel, varscan2
- PDE4B | c.1264C>A p.L422I | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLA2R1 | c.607T>C p.W203R | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLD1 | c.2212G>A p.V738I | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRDM9 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 51/457 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); called by muse, varscan2
- RAD9B | c.480T>G p.I160M | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- RASGRF1 | c.680A>T p.Q227L | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- RECK | c.2497A>T p.R833* | Nonsense Mutation (SNP) | VAF 15/113 reads (13%) | called by muse, mutect2, varscan2
- RP2 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SASS6 | c.5G>C p.S2T | Missense Mutation (SNP) | VAF 59/277 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SCN8A | c.1016G>C p.C339S | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2
- SEMG2 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM221 | c.379T>A p.C127S | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TRAPPC10 | c.815T>A p.F272Y | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- VLDLR | c.204A>T p.V68= | Splice Region (SNP) | VAF 95/416 reads (23%) | called by muse, mutect2, varscan2
- ANKRD30B | c.2946T>C p.C982= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- CMTM4 | c.522A>G p.K174= | Silent (SNP) | VAF 65/356 reads (18%) | called by muse, mutect2, varscan2
- DICER1 | c.4359A>T p.I1453= | Silent (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- OVCH1 | c.1251A>T p.S417= | Silent (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- PHF3 | c.4458A>G p.S1486= | Silent (SNP) | VAF 24/158 reads (15%) | called by muse, mutect2, varscan2
- PRC1 | c.90G>A p.G30= | Silent (SNP) | VAF 37/261 reads (14%) | called by muse, mutect2, varscan2
- SAMD9L | c.4620A>T p.T1540= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- SPPL2A | c.666A>T p.T222= | Silent (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- SPRR1A | c.222T>A p.P74= | Silent (SNP) | VAF 36/195 reads (18%) | called by muse, mutect2, varscan2
- TEX15 | c.5076A>G p.E1692= (on ENST00000256246; = p.E2075= on NM_001350162.2) | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- TTR | c.66T>A p.P22= | Silent (SNP) | VAF 67/498 reads (13%) | called by muse, mutect2, varscan2
- VWA5B1 | c.1602C>G p.A534= | Silent (SNP) | VAF 35/202 reads (17%) | called by muse, mutect2, varscan2
- WTIP | c.855G>A p.Q285= | Silent (SNP) | VAF 20/351 reads (6%) | called by muse, mutect2
- ZIC5 | c.198C>T p.S66= | Silent (SNP) | VAF 22/418 reads (5%) | catalogued as rs1195059092; called by muse, mutect2
- AC244394.2 | n.849C>T | RNA (SNP) | VAF 48/287 reads (17%) | called by muse, mutect2, varscan2
- AP001360.1 | n.3734G>A | RNA (SNP) | VAF 27/176 reads (15%) | catalogued as rs749613334; called by muse, mutect2, varscan2
- CD84 | c.812-32A>T | Intron (SNP) | VAF 24/206 reads (12%) | called by muse, mutect2, varscan2
- EEF1E1 | c.384+10del | Intron (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel
- LINC02253 | n.575-1318C>G | Intron (SNP) | VAF 50/272 reads (18%) | called by muse, mutect2, varscan2
- LRRK2 | c.347+34T>G | Intron (SNP) | VAF 27/138 reads (20%) | called by muse, mutect2, varscan2
- MIR296 | chr20:58817701 T>A | 5'Flank (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- PAX2 | c.-14T>A | 5'UTR (SNP) | VAF 81/436 reads (19%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67988C>G | Intron (SNP) | VAF 27/188 reads (14%) | called by muse, mutect2, varscan2
- PON2 | c.778-16dup | Intron (INS) | VAF 23/228 reads (10%) | called by mutect2, pindel, varscan2
